Somatic mutation profile of tumor specimen TCGA-MB-A8JL-01A (aliquot TCGA-MB-A8JL-01A-11D-A36J-09) from TCGA case TCGA-MB-A8JL, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Age at diagnosis: 53.4 years (19,510 days).
Specimen TCGA-MB-A8JL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c4579f3d-0b76-45e5-b656-0418942bb69e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MB-A8JL-10A (Blood Derived Normal), aliquot TCGA-MB-A8JL-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a2cd9a7-3bb4-4dd0-a3a2-2f30f01276e1

The open-access MAF lists 34 somatic variants for this specimen: 29 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 28, Silent 5, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.843C>G p.D281E | Missense Mutation (SNP) | VAF 20/44 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs1057519984, CM137620, COSV52664212, COSV52688790, COSV52719382, COSV53103731; ClinVar: likely pathogenic / uncertain significance; called by muse, varscan2
- TP53 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 18/41 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912657, CM130241, CM920676, COSV52661812, COSV52677483, COSV52701127; ClinVar: likely pathogenic / uncertain significance; called by muse, varscan2
- ADI1 | c.428C>T p.T143M | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as rs748218756, COSV100537778; called by muse, mutect2, varscan2
- ANKRD26 | c.1316G>T p.G439V | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.112); catalogued as COSV101066455; called by muse, mutect2, varscan2
- CABIN1 | c.6353A>C p.K2118T | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.991); catalogued as COSV99573401; called by muse, mutect2, varscan2
- CHODL | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 43/80 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202176979, COSV54731563; called by muse, mutect2, varscan2
- CLRN2 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs201748212, COSV72512547; called by muse, mutect2, varscan2
- EXD3 | c.2146G>A p.V716M | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs757839885, COSV100573765; called by muse, mutect2, varscan2
- FDXACB1 | c.1537C>T p.R513C | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs374516075; called by muse, mutect2, varscan2
- FLG | c.6658T>C p.S2220P | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.225); catalogued as COSV100911663; called by muse, mutect2
- FLNB | c.4042G>T p.V1348F | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV99913581; called by muse, mutect2
- GORASP2 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761491954, COSV99304591; called by muse, mutect2, varscan2
- HRNR | c.8200G>C p.D2734H | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.094); catalogued as COSV100913580; called by muse, varscan2
- HRNR | c.5609G>A p.G1870E | Missense Mutation (SNP) | VAF 60/636 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.08); catalogued as COSV64254988; called by muse, mutect2, varscan2
- IKZF2 | c.470G>T p.R157I | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100563617; called by muse, mutect2, varscan2
- LMTK2 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.564); catalogued as rs747890701, COSV99807036; called by muse, mutect2, varscan2
- MAML3 | c.553T>C p.F185L | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.65); PolyPhen benign (0.444); catalogued as COSV100505217; called by muse, mutect2, varscan2
- MAS1L | c.1017T>A p.D339E | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV101009702; called by muse, mutect2, varscan2
- NPAP1 | c.2755C>T p.P919S | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.475); catalogued as rs758481864, COSV61508416; called by muse, mutect2, varscan2
- OGDHL | c.2791G>A p.A931T | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV100934374; called by muse, mutect2, varscan2
- OR2AT4 | c.947G>A p.C316Y | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); catalogued as COSV59406587; called by muse, mutect2, varscan2
- PHETA1 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.488); catalogued as rs768087955, COSV64058996; called by muse, mutect2, varscan2
- RPL5 | c.299G>T p.C100F | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as COSV100240398; called by muse, mutect2, varscan2
- SMG5 | c.2054G>T p.R685L | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100700811; called by muse, mutect2, varscan2
- SMPDL3B | c.1165C>A p.L389M | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV100874584; called by muse, mutect2, varscan2
- TACC2 | c.6067G>A p.V2023I (on ENST00000334433; = p.V101I on NM_006997.4) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs1008585258, COSV99586808; called by muse, mutect2, varscan2
- TNRC18 | c.7147C>T p.R2383* | Nonsense Mutation (SNP) | VAF 9/18 reads (50%) | catalogued as rs1266612409, COSV60310527; called by muse, mutect2, varscan2
- TNRC18 | c.2162G>T p.R721L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as COSV101269703; called by muse, varscan2
- ZBTB4 | c.1850G>A p.R617H | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.5); PolyPhen benign (0.354); catalogued as rs200881841, COSV60984843; called by muse, mutect2, varscan2
- ACTN3 | c.2604C>T p.Y868= | Silent (SNP) | VAF 36/74 reads (49%) | catalogued as COSV100074342; called by muse, mutect2, varscan2
- ENPP3 | c.1332G>A p.L444= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as rs747144335, COSV100717469; called by muse, mutect2, varscan2
- ITGAM | c.2706G>A p.V902= (on ENST00000648685 / NM_001145808.2; = p.V901= on NM_000632.4) | Silent (SNP) | VAF 67/85 reads (79%) | catalogued as COSV54939367, COSV99792565; called by muse, mutect2, varscan2
- MED16 | c.2127G>A p.P709= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs376670615; called by muse, mutect2, varscan2
- PRKCZ | c.603C>T p.D201= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as rs757956708, COSV66067947; called by muse, mutect2, varscan2
